Gene-level copy-number profile of tumor specimen ALCH-AFEE-TTP1-A from ALCHEMIST case ALCH-AFEE, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.7 years (24,347 days).
Specimen ALCH-AFEE-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 789444ed-b7f2-4ab0-b7bc-5b5c56de2911.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AFEE-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,223 have no estimate.
https://portal.gdc.cancer.gov/files/60b73a11-c208-4d44-ab42-18bbfc9b8d4c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 70; copy number 1: 1,844; copy number 2: 53,799; copy number 3: 2,657; copy number 4: 7; copy number 5: 8; copy number 6: 1; copy number 7: 3; copy number 8: 1; copy number 9: 5; copy number 10: 1; copy number 13: 2; copy number 15: 2.

Homozygous deletions (total copy number 0; autosomes only): 70 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:32,741,830–32,774,970, 1 gene: KIAA1522.
- chr2:10,721,100–10,785,110, 3 genes (within-gene range 0–2): ATP6V1C2, RNU7-138P, AC092687.3.
- chr2:202,995,194–202,995,403, 1 gene (within-gene range 0–2): AC010900.1.
- chr2:232,479,827–232,487,834, 1 gene: ECEL1.
- chr3:48,561,718–48,610,976, 4 genes (within-gene range 0–2): UCN2, COL7A1, MIR711, UQCRC1.
- chr3:50,558,025–50,596,168, 2 genes: C3orf18, HEMK1.
- chr3:196,999,460–197,004,744, 1 gene (within-gene range 0–2): MELTF-AS1.
- chr5:1,510,762–1,510,856, 1 gene (within-gene range 0–2): MIR6075.
- chr5:99,522,311–99,534,611, 2 genes: AC114324.1, GUSBP8.
- chr14:105,419,820–105,470,729, 2 genes (within-gene range 0–2): MTA1, AL928654.2.
- chr15:25,159,221–25,250,940, 46 genes (within-gene range 0–2): SNORD115, DMAC1P1, SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr17:2,030,137–2,044,968, 5 genes: DPH1, AC090617.10, OVCA2, AC090617.3, AC090617.5.
- chr22:18,533,646–18,577,968, 1 gene: PI4KAP1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 23 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:1,947,278–2,001,470, 7 genes, copy number 7–13: MRPL23, MRPL23-AS1, LINC01219, H19, AC051649.3, MIR675, AC051649.2.
- chr14:75,002,921–75,012,851, 3 genes, copy number 5: EIF2B2, AL049780.1, AL049780.3.
- chr21:44,107,373–44,131,181, 1 gene, copy number 8: PWP2.
- chr21:44,172,169–44,194,338, 2 genes, copy number 5: AP001056.2, AP001056.1.
- chr22:18,527,157–18,530,573, 2 genes, copy number 7: AC023490.3, TMEM191B.
- chr22:18,605,355–18,719,341, 8 genes, copy number 5–15: AC023490.1, RN7SKP131, RIMBP3, Metazoa_SRP, SUSD2P2, CA15P2, PPP1R26P2, PPP1R26P4.

Autosomal genes at a single copy (total copy number 1): 1,844. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
